Gene-level copy-number profile of tumor specimen HTMCP-03-06-02185-01A from CGCI case HTMCP-03-06-02185, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3.
Specimen HTMCP-03-06-02185-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e2fca7ef-e06e-4f1f-a66e-f5ea41ed1707.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02185-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,241 have no estimate.
https://portal.gdc.cancer.gov/files/6eda2818-5bb9-4813-9c3f-1b306d37b3ff

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 355; copy number 2: 8,944; copy number 3: 15,780; copy number 4: 30,863; copy number 5: 1,844; copy number 6: 448; copy number 8: 62; copy number 10: 71.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:257,864–522,928, 10 genes (within-gene range 0–2): AP006222.1, AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6.
- chr1:587,629–594,768, 1 gene: AC114498.1.
- chr7:5,871,753–5,970,683, 4 genes: RN7SL556P, OCM, CCZ1, RSPH10B.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 71 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–1,386,409, 51 genes, copy number 10: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, LINC01511, MTCO2P32, AC026748.3.
- chr5:1,544,107–2,119,926, 20 genes, copy number 10: AC091849.2, SDHAP3, AC026412.3, AC091849.1, AC026412.1, AC026412.2, MIR4277, AC112176.1, MRPL36, NDUFS6, AC025183.1, LINC02116, AC025183.2, IRX4, IRX4-AS1, CTD-2194D22.4, AC126768.3, AC124852.1, AC126768.1, AC126768.2.

Autosomal genes at a single copy (total copy number 1): 355. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
